TARGET case TARGET-10-PASGFH — Acute Lymphoblastic Leukemia - Phase II (TARGET-ALL-P2)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Lymphoid Leukemias; Primary site: Hematopoietic and reticuloendothelial systems. Index date (day 0 for every day count below): diagnosis.
https://portal.gdc.cancer.gov/cases/e7f47813-0ed4-51a8-b9fd-ae4ef0aebd3a

Demographics
Sex at birth: male; Race: black or african american; Ethnicity: not hispanic or latino; Age at index: 17 years; Vital status: Alive.

Diagnoses (1)
1. Acute lymphocytic leukemia: ICD-O-3 morphology code: 9835/3; ICD-10 code: C91.0; Tissue or organ of origin: Bone marrow; Classification of tumor: primary; Age at diagnosis: 17.8 years (6,488 days); Year of diagnosis: 2008; Days to last follow up: 1,206 days (3.3 years).
   Treatment given: Protocol identifier: AALL0434.

Follow-up (1 entry)
- Days to follow up: 1,206 days (3.3 years); Progression or recurrence: Yes; Progression or recurrence anatomic site: Bone marrow; Event-free: no event (relapse, second malignancy or death) recorded through day 1,206; Year of follow up: 2012.

Molecular and laboratory tests (laboratory values grouped by visit day)
- BCR–ABL1 fusion: Negative.
- Day 0: Leukocytes 7.77 ×10³/µL; Bone Marrow blast count 85%.
- Day 8: Bone Marrow blast count 40%.
- Day 15: Bone Marrow blast count 24%.
- Day 29: Bone Marrow blast count 2%; Minimal Residual Disease (Flow Cytometry) 1.3%.
- Minimal Residual Disease (Flow Cytometry) 0%.

Biospecimens (2 samples)
- Sample TARGET-10-PASGFH-09A: Sample type: Primary Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Bone Marrow NOS.
- Sample TARGET-10-PASGFH-10A: Sample type: Blood Derived Normal; Tissue type: Normal; Specimen type: Peripheral Blood NOS.

Additional fields from the TARGET clinical supplement workbook TARGET_ALL_Blast_Data_20230727.xlsx, for sample TARGET-10-PASGFH-09A-01D:
- Blast %: yes many

Additional fields from the TARGET clinical supplement workbook TARGET_ALL_ClinicalData_Phase_II_Validation_20230727.xlsx:
- First Event: Censored
- Overall Survival Time in Days: 1206
- WBC at Diagnosis: 7.77
- CNS Status at Diagnosis: CNS 1
- Testicular Involvement: No
- MRD Day 29: 1.3
- MRD Day 29 Sensitivity: 0.01
- MRD End Consolidation: 0
- Bone Marrow Site of Relapse: Yes
- CNS Site of Relapse: No
- Testes Site of Relapse: No
- Other Site of Relapse: No
- BCR ABL1 Status: Negative
- BMA Blasts Day 8: 40
- BMA Blasts Day 15: 24
- BMA Blasts Day 29: 2
- Down Syndrome: No
- DNA Index: 1
- Cell of Origin: T Cell ALL

Additional fields from the TARGET clinical supplement workbook TARGET_ALL_ClinicalData_Validation_Supplement_20230727.xlsx:
- BM Blasts at Diagnosis: 85
- Group: TAL1
- Lesion: wt
